Gene-level copy-number profile of tumor specimen TCGA-CR-5247-01A from TCGA case TCGA-CR-5247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 48.8 years (17,810 days).
Specimen TCGA-CR-5247-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.424ca0d1-7291-4b1f-ac3f-d9faaa4b27fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-5247-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87cc2960-d2e9-4a88-9e7c-05fcd2c7fa59

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 813; copy number 2: 13,584; copy number 3: 17,726; copy number 4: 15,333; copy number 5: 10,135; copy number 6: 409; copy number 7: 435; copy number 8: 60; copy number 9: 974; copy number 10: 130; copy number 11: 63; copy number 12: 7; copy number 14: 18; copy number 17: 2; copy number 20: 4; copy number 21: 50; copy number 23: 20; copy number 29: 13; copy number 41: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-5247-01A-01D-2010-01): tumor purity 0.64, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,820 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,944,428–198,222,513, 974 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:89,882,353–109,660,802, 454 genes, copy number 7–21 (broad region; genes not listed).
- chr11:68,870,664–72,080,693, 101 genes, copy number 7–23 (within-gene range 4–23) (broad region; genes not listed).
- chr11:92,748,732–92,766,867, 1 gene, copy number 11: AP003718.1.
- chr11:95,821,766–95,925,315, 1 gene, copy number 14 (within-gene range 4–14): MTMR2.
- chr11:95,963,219–103,895,271, 86 genes, copy number 8–41 (broad region; genes not listed).
- chr13:70,923,664–81,302,407, 130 genes, copy number 10 (broad region; genes not listed).
- chr13:87,427,214–88,236,969, 10 genes, copy number 8 (within-gene range 3–8): MIR4500HG, AL355578.1, MIR4500, SLITRK5, AL445647.2, LINC00397, AL445647.1, TET1P1, LINC00373, RPL29P29.
- chr18:1,883,524–4,459,458, 54 genes, copy number 11–17: AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27.
- chr18:30,290,161–30,780,424, 4 genes, copy number 20: AC115100.1, MIR302F, AC090506.1, AC090506.2.
- chr18:33,851,100–34,226,429, 5 genes, copy number 8: NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
